Somatic mutation profile of tumor specimen MP2PRT-PAUGBT-TMP1-A (aliquot MP2PRT-PAUGBT-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUGBT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,492 days).
Specimen MP2PRT-PAUGBT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 414f7248-bc8d-477f-9199-a6eb127d3751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGBT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGBT-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99f5c640-9ae4-4621-a944-9766a1721cb8

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK2 | c.330C>A p.F110L | Missense Mutation (SNP) | VAF 374/886 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV50783270, COSV99301978; called by muse, mutect2, varscan2
- EBI3 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 238/543 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs753728633; called by muse, mutect2, varscan2
- OR2T6 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 65/994 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs201925418, COSV63216883; called by muse, mutect2
- RBM33 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 236/547 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs960003380, COSV56637856; called by muse, mutect2, varscan2
- WNT10B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536694627, COSV56404859, COSV56405318; called by muse, mutect2, varscan2
- CCDC144A | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 122/292 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRRC2C | c.1778A>C p.K593T (on ENST00000367742; = p.K591T on NM_015172.4) | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET3 | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 259/633 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MCC | c.1152C>T p.H384= | Silent (SNP) | VAF 167/412 reads (41%) | catalogued as rs747470968; called by muse, mutect2, varscan2
- PLD1 | c.2223C>T p.N741= | Silent (SNP) | VAF 97/262 reads (37%) | catalogued as rs757293042, COSV60572979; called by muse, mutect2, varscan2
- XKR3 | c.348C>T p.T116= | Silent (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
